Surgical pathology report (de-identified scan), TCGA case TCGA-28-5216, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-5216-01A (Primary Tumor).

[page 1 of 10]
Patient: [REDACTED]

Accession Number: [REDACTED]

Hospital No: [REDACTED]

Pathologist: [REDACTED]

Ordering M.D.: [REDACTED]

Date of Birth: [REDACTED]

Assistant: [REDACTED]

Age/Sex: [REDACTED]

Date of Procedure: [REDACTED]

Copies To: [REDACTED]

Date Received: [REDACTED]

Location: [REDACTED]

TCGA-28-5216

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. BRAIN, RIGHT TEMPORAL, BIOPSY:

- Glioblastoma multiforme, WHO grade IV ✓

B. BRAIN, RIGHT TEMPORAL, BIOPSY:

- Glioblastoma multiforme, WHO grade IV

C. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #1:

- Glioblastoma multiforme, WHO grade IV
- 5% of tumor necrosis
- 90% of tumor cellularity

D. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #2:

- Glioblastoma multiforme, WHO grade IV
- 5% of tumor necrosis
- 90% of tumor cellularity

E. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to [REDACTED]. Hence, the 20% result in this case suggests the possibility of a relatively diminished response to [REDACTED].

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED]. Hence the preserved expression of PTEN in this case, when combined with EGFRvIII mutation, permits a possibility of this tumor being responsive to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas [REDACTED].

[REDACTED] subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell. [REDACTED]

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas.

[REDACTED] Association between laminin-8 and glial tumor grade, recurrence, and patient survival.

Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Patient Case(s) [REDACTED]

Copy For: [REDACTED]
Page 1 of 5

PATIENT NOTIFIED OF RESULTS		
DR:	NURSE:	DATE:

[page 2 of 10]
PATIENT:

***** Addendum - Please See End of Report *****
ACCESSION #:

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) often is indicative of an upregulation of receptor tyrosine kinase signaling. It has been shown to be associated with a relative resistance to radiation therapy in glioblastoma multiforme

Correspondingly, a high percentage of tumor cells immunoreactive to pMAPK antibody in this case may predict a relative resistance to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

HISTORY:

None provided

MICROSCOPIC FINDINGS:

Sections disclose focally necrotizing astrocytoma composed of hyperchromatic irregularly shaped nuclei associated with endothelial proliferation, mitotic figures and palisading necrosis. Giant cells are frequently seen.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
MGMT	C1	Up to 20%
PTEN	C1	Retained (2+ in 80% of tumor cells)
pMAPK	C1	Up to 70% of tumor nuclei and 90% of cytoplasm is positive
Laminin beta-1 (8/411)	C1	Upregulated (2+ in endothelial and focal staining of tumor cells)
Laminin beta-2 (9/421)	C1	Downregulated
EGFR by FISH	C1	Pending

GROSS:

A. RIGHT TEMPORAL TUMOR FS#1

Labeled with the patient's name, labeled "right temporal tumor FS#1", and received fresh in the Operating Room for frozen section evaluation and subsequently fixed in formalin are six portions of tan soft tissue ranging from 0.1 to 1.3 cm in greatest dimension, and aggregating to 1.5 x 1.0 x 0.3 cm.

Entirely submitted.

Slide key:

- A1. Frozen section remnant FSA - 1
- A2. Remainder of specimen - 6

B. RIGHT TEMPORAL FS#2

Labeled with the patient's name, labeled "right temporal FS#2", and received fresh in the Operating Room for frozen section evaluation and subsequently fixed in formalin is one portion of tan soft tissue measuring 1.1 x 1.1 x 0.5 cm. Also received is a 0.9 x 0.4 x 0.3 cm portion of blood clot.

The surface consists of tan smooth, glistening tissue. Sectioning reveals tan-yellow soft tissue. Entirely submitted.

Slide key:

- B1. Frozen section remnant FSB - multiple

[page 3 of 10]
PATIENT: [REDACTED]

***** Addendum - Please See End of Report *****

ACCESSION #: [REDACTED]

B2. Remainder of the specimen - 5

C. RIGHT TEMPORAL MCI #1

Labeled with the patient's name, labeled "right temporal MCI #1", and received in formalin is a 1.1 x 1.0 x 0.2 cm portion of tan soft tissue. Entirely submitted.

Slide key:

C1. 1

D. RIGHT TEMPORAL MCI #2

Labeled with the patient's name, labeled "right temporal MCI #2", and received in formalin is a 0.7 x 0.5 x 0.2 cm portion of tan soft tissue. Entirely submitted.

Slide key:

D1. 1

E. RIGHT TEMPORAL TUMOR (PERMANENT)

Labeled with the patient's name, labeled "right temporal tumor (permanent)", and received in formalin is one tan-red portion of tissue measuring 0.7 x 0.5 x 0.4 cm. Tan soft tissue is surrounded by adherent red hemorrhage. Entirely submitted.

Slide key:

E1. Trisected - 3

[REDACTED]
INTRAOPERATIVE CONSULTATION:

OPERATIVE CALL

OPERATIVE CONSULTATION (FROZEN):

A. RIGHT TEMPORAL FS AND TP:

- Necrosis with rare atypical nuclei

B. RIGHT TEMPORAL FS AND TP:

- Infiltrating astrocytoma

[REDACTED]
I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
[REDACTED]

[page 4 of 10]
PATIENT:

[REDACTED]

***** Addendum - Please See End of Report *****
ACCESSION #: [REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 5 of 10]
PATIENT: [REDACTED]

***** Addendum - Please See End of Report *****

ACCESSION #: [REDACTED]

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) for EGFR in BRAIN

Tissue Block: [REDACTED]

RESULTS: NORMAL EGFR & chromosome 7 signal pattern

Number of cells evaluated: 40

INTERPRETATION:

Fluorescence in situ hybridization (FISH) analysis on a brain tumor sample from this patient with Abbott Molecular probes specific for the centromere of chromosome 7 (control probe) and the short arm (EGFR-7p12) of chromosome 7 was performed. The control sample gave expected results.

These studies did not detect any aberrant signal patterns of EGFR in the 40 nuclei examined, with an EGFR gene to Cep 7 signal ratio of 1.1

NOTE:

1. Samples are considered positive in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells or tumors with four or more copies of the EGFR gene in $\geq 40\%$ of the cells (high polysomy).
2. Samples are considered inconclusive, requiring consult with the pathologist, in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $<10\%$ of analyzed cells or when four or more copies of the EGFR gene in $<40\%$ of the cells.

References:

[REDACTED]

These FISH tests were developed and their performance characteristics determined by [REDACTED] Laboratory as required by the CLIA [REDACTED] regulations. They have not been cleared or approved for specific uses by the U.S. Food and Drug Administration.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED] Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

[page 6 of 10]
[REDACTED]

Patient: [REDACTED] Accession Number: [REDACTED]
Hospital No.: [REDACTED] Pathologist: [REDACTED] Ordering M.D.: [REDACTED]
Date of Birth: [REDACTED] Assistant: [REDACTED]
Age/Sex: [REDACTED] Date of Procedure: [REDACTED] Copies To: [REDACTED]
Location: [REDACTED] Date Received: [REDACTED]

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

- A. BRAIN, RIGHT TEMPORAL, BIOPSY:
- Glioblastoma multiforme, WHO grade IV ✓
- B. BRAIN, RIGHT TEMPORAL, BIOPSY:
- Glioblastoma multiforme, WHO grade IV
- C. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #1:
- Glioblastoma multiforme, WHO grade IV
- 5% of tumor necrosis
- 90% of tumor cellularity
- D. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #2:
- Glioblastoma multiforme, WHO grade IV
- 5% of tumor necrosis
- 90% of tumor cellularity
- E. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:
- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to [REDACTED]. Hence, the 20% result in this case suggests the possibility of a relatively diminished response to [REDACTED].

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED]. Hence the preserved expression of PTEN in this case, when combined with EGFRvIII mutation, permits a possibility of this tumor being responsive to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas [REDACTED].

subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell. [REDACTED]

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas.

[REDACTED] Association between laminin-8 and glial tumor grade, recurrence, and patient survival.

Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Patient Case(s) [REDACTED]

Copy For: [REDACTED]
Page 1 of 5

PATIENT REPORT TO RESULTS
OF NURSE DATE

[page 7 of 10]
PATIENT: [REDACTED] ***** Addendum - Please See End of Report *****
ACCESSION #: [REDACTED]

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) often is indicative of an upregulation of receptor tyrosine kinase signaling. It has been shown to be associated with a relative resistance to radiation therapy in glioblastoma multiforme [REDACTED]

Correspondingly, a high percentage of tumor cells immunoreactive to pMAPK antibody in this case may predict a relative resistance to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

HISTORY:
None provided ✓

MICROSCOPIC FINDINGS:

Sections disclose focally necrotizing astrocytoma composed of hyperchromatic irregularly shaped nuclei associated with endothelial proliferation, mitotic figures and palisading necrosis. Giant cells are frequently seen.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
MGMT	C1	Up to 20%
PTEN	C1	Retained (2+ in 80% of tumor cells)
pMAPK	C1	Up to 70% of tumor nuclei and 90% of cytoplasm is positive
Laminin beta-1 (8/411)	C1	Upregulated (2+ in endothelial and focal staining of tumor cells)
Laminin beta-2 (9/421)	C1	Downregulated
EGFR by FISH	C1	Pending

GROSS:

A. RIGHT TEMPORAL TUMOR FS#1

Labeled with the patient's name, labeled "right temporal tumor FS#1", and received fresh in the Operating Room for frozen section evaluation and subsequently fixed in formalin are six portions of tan soft tissue ranging from 0.1 to 1.3 cm in greatest dimension, and aggregating to 1.5 x 1.0 x 0.3 cm.

Entirely submitted.

Slide key:

- A1. Frozen section remnant FSA - 1
- A2. Remainder of specimen - 6

B. RIGHT TEMPORAL FS#2

Labeled with the patient's name, labeled "right temporal FS#2", and received fresh in the Operating Room for frozen section evaluation and subsequently fixed in formalin is one portion of tan soft tissue measuring 1.1 x 1.1 x 0.5 cm. Also received is a 0.9 x 0.4 x 0.3 cm portion of blood clot.

The surface consists of tan smooth, glistening tissue. Sectioning reveals tan-yellow soft tissue. Entirely submitted.

Slide key:

- B1. Frozen section remnant FSB - multiple

SURGICAL PATHOLOGY REPORT

[page 8 of 10]
PATIENT: [REDACTED]

***** Addendum - Please See End of Report *****
ACCESSION #: [REDACTED]

B2. Remainder of the specimen - 5

C. RIGHT TEMPORAL MCI #1

Labeled with the patient's name, labeled "right temporal MCI #1", and received in formalin is a 1.1 x 1.0 x 0.2 cm portion of tan soft tissue. Entirely submitted.

Slide key:

C1. 1

D. RIGHT TEMPORAL MCI #2

Labeled with the patient's name, labeled "right temporal MCI #2", and received in formalin is a 0.7 x 0.5 x 0.2 cm portion of tan soft tissue. Entirely submitted.

Slide key:

D1. 1

E. RIGHT TEMPORAL TUMOR (PERMANENT)

Labeled with the patient's name, labeled "right temporal tumor (permanent)", and received in formalin is one tan-red portion of tissue measuring 0.7 x 0.5 x 0.4 cm. Tan soft tissue is surrounded by adherent red hemorrhage. Entirely submitted.

Slide key:

E1. Trisected - 3

Gross dictated by [REDACTED]

INTRAOPERATIVE CONSULTATION:

OPERATIVE CALL

OPERATIVE CONSULTATION (FROZEN):

A. RIGHT TEMPORAL FS AND TP:

- Necrosis with rare atypical nuclei

B. RIGHT TEMPORAL FS AND TP:

- Infiltrating astrocytoma

[REDACTED]
I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
[REDACTED]

[page 9 of 10]
PATIENT:

***** Addendum - Please See End of Report *****
ACCESSION #:

SURGICAL PATHOLOGY REPORT

[page 10 of 10]
PATIENT: [REDACTED]

***** Addendum - Please See End of Report *****

ACCESSION #: [REDACTED]

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) for EGFR in BRAIN

Tissue Block: [REDACTED]

RESULTS: NORMAL EGFR & chromosome 7 signal pattern

Number of cells evaluated: 40

INTERPRETATION:

Fluorescence in situ hybridization (FISH) analysis on a brain tumor sample from this patient with Abbott Molecular probes specific for the centromere of chromosome 7 (control probe) and the short arm (EGFR-7p12) of chromosome 7 was performed. The control sample gave expected results.

These studies did not detect any aberrant signal patterns of EGFR in the 40 nuclei examined, with an EGFR gene to Cep 7 signal ratio of 1.1

NOTE:

1. Samples are considered positive in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells or tumors with four or more copies of the EGFR gene in $\geq 40\%$ of the cells (high polysomy).
2. Samples are considered inconclusive, requiring consult with the pathologist, in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $<10\%$ of analyzed cells or when four or more copies of the EGFR gene in $< 40\%$ of the calls.

References:

[REDACTED]

These FISH tests were developed and their performance characteristics determined by [REDACTED] Laboratory as required by the CLIA [REDACTED] regulations. They have not been cleared or approved for specific uses by the U.S. Food and Drug Administration.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED] those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file 1104edf3-e6c1-4c75-91cc-90bb733c6a52 (TCGA-28-5216.69F3D1FF-0B60-4841-B83C-AB9E707B5FF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).